Gene-level copy-number profile of tumor specimen TCGA-DU-5872-02A from TCGA case TCGA-DU-5872, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 43.8 years (15,986 days).
Specimen TCGA-DU-5872-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.9dfc7c34-e572-4e1f-80a0-a5d00c639e04.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-5872-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 354 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3109fa42-f126-4163-9cb2-b644703e8cf4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 1: 2,037; copy number 2: 57,488; copy number 3: 33; copy number 4: 6; copy number 5: 1; copy number 6: 164; copy number 8: 2; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-5872-02A-21D-A36N-01): tumor purity 1, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:55,662,201–55,828,154, 13 genes: OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2.
- chr14:45,502,742–45,503,140, 1 gene: AL162632.2.
- chr21:25,515,349–25,518,865, 1 gene: AP000221.1.
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 167 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:146,340,420–146,340,524, 1 gene, copy number 5: RNA5SP222.
- chr14:22,630,929–22,644,352, 1 gene, copy number 8 (within-gene range 1–8): OR6J1.
- chr14:105,785,505–106,715,181, 164 genes, copy number 6 (broad region; genes not listed).
- chr19:15,673,018–15,697,174, 1 gene, copy number 8 (within-gene range 2–8): CYP4F12.

Autosomal genes at a single copy (total copy number 1): 2,035. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
